TCGA case TCGA-DS-A3LQ — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/63bffdb1-bc08-4175-8be7-d7a056d19816

Demographics
Sex at birth: female; Country of residence at enrollment: United States; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 46.2 years (16,861 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; AJCC pathologic T: T3b; AJCC pathologic N: N1; AJCC pathologic M: M0; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 699 days (1.9 years).
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 8; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 54 days; Days to treatment end: 89 days; Number of cycles: 6; Treatment dose: 427 mg; Prescribed dose: 40; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 90 days; Treatment dose: 4,500 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.

Follow-up (3 entries)
- Day 2 (preoperative): ECOG performance status: 1.
- Days to follow up: 699 days (1.9 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 183.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 163 cm; BMI: 27.1.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1978.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DS-A3LQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-DS-A3LQ-01A-02-TSB: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DS-A3LQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DS-A3LQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Live birth pregnancy count: 2; Pregnant at diagnosis: No; Total pregnancy count: 7; Tobacco smoking history indicator: 3; Days from index date to performance status: 2; Tumor response: Complete response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Cone Biopsy / LEEP; Margins involved hysterectomy: Other Location, specify; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymphovascular invasion: Present.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; Radiation adjuvant indicator: Yes; Chemo concurrent dose: 40 mg/m2; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 6; New tumor event diagnosis indicator: No.
- Follow-up form 1, Radiation supplemental: Radiation therapy status: Completed as Planned.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 699 days; disease-specific survival: no event (censored), 699 days; disease-free interval: no event (censored), 699 days; progression-free interval: no event (censored), 699 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DS-A3LQ-01A-21D-A21P-01): tumor purity 0.72, ploidy 2.63, whole-genome doublings 1.
